Gene-level copy-number profile of tumor specimen TCGA-UF-A719-01A from TCGA case TCGA-UF-A719, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 54.2 years (19,797 days).
Specimen TCGA-UF-A719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b7e8ecfd-e0cd-407f-b3a2-461e2fc97d3c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A719-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/03cc7612-3af0-47d8-aacf-75dd1e0c1fe9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 2,139; copy number 2: 22,973; copy number 3: 15,739; copy number 4: 17,223; copy number 5: 624; copy number 6: 956; copy number 7: 41; copy number 8: 34; copy number 15: 1; copy number 21: 2.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:76,990,660–85,969,533, 86 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,658 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,238,686–189,897,276, 4 genes, copy number 5–8: TPRG1-AS2, TP63, AC078809.1, MIR944.
- chr4:47,593,999–47,838,106, 1 gene, copy number 5 (within-gene range 3–5): CORIN.
- chr4:47,706,372–48,269,838, 11 genes, copy number 5: AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA.
- chr4:54,603,211–56,710,614, 53 genes, copy number 5: LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20.
- chr4:57,841,721–58,565,212, 5 genes, copy number 5: AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1.
- chr5:133,160,438–135,358,219, 63 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:114,523,443–142,753,759, 385 genes, copy number 5 (broad region; genes not listed).
- chr6:162,568,379–164,152,175, 21 genes, copy number 7: KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3.
- chr10:27,672,874–28,682,932, 22 genes, copy number 5: MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI.
- chr11:45,240,302–45,286,341, 1 gene, copy number 6 (within-gene range 4–6): SYT13.
- chr11:45,355,371–46,239,267, 29 genes, copy number 6: LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1.
- chr13:65,309,855–68,986,064, 31 genes, copy number 6: STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4.
- chr13:69,700,594–75,482,169, 55 genes, copy number 7–21 (within-gene range 4–21): KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1.
- chr14:46,839,629–51,979,342, 109 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:96,045,341–96,064,357, 1 gene, copy number 8: AC024337.1.
- chr15:100,919,327–101,933,350, 35 genes, copy number 5 (within-gene range 3–5): LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr18:47,390–15,330,282, 376 genes, copy number 6 (broad region; genes not listed).
- chr19:15,226,919–24,163,425, 456 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,363. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
